Somatic mutation profile of tumor specimen TARGET-10-PANXTP-09A (aliquot TARGET-10-PANXTP-09A-01D) from TARGET case TARGET-10-PANXTP, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,093 days).
Specimen TARGET-10-PANXTP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b27aecb9-234f-42b6-a83e-d1cd49140813.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANXTP-14A (Bone Marrow Normal), aliquot TARGET-10-PANXTP-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d1cd35f1-1c89-4715-a461-a37bf4c75b2d

The open-access MAF lists 57 somatic variants for this specimen: 35 protein-altering or splice-affecting, 12 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 12, Intron 7, Nonsense Mutation 3, 5'UTR 2, Splice Site 1, RNA 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB9 | c.2110G>A p.V704M (on ENST00000280560 / NM_019625.4; = p.V661M on NM_019624.3) | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs997728616, COSV54892944; called by muse, mutect2, varscan2
- AXDND1 | c.1290G>A p.W430* | Nonsense Mutation (SNP) | VAF 6/60 reads (10%) | catalogued as COSV100858419, COSV62650338; called by muse, mutect2, varscan2
- CREBBP | c.4427C>T p.P1476L | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52113088, COSV52117573; called by muse, mutect2
- DLG2 | c.2602G>A p.E868K | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1406918822, COSV54648141; called by muse, mutect2
- DNAH11 | c.5189G>A p.R1730K | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.615); catalogued as COSV60937394; called by muse, mutect2, varscan2
- MUSK | c.13G>A p.V5I | Missense Mutation (SNP) | VAF 48/239 reads (20%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs765874906, COSV51885443; called by muse, mutect2, varscan2
- MYH6 | c.3379G>A p.E1127K | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1170646537, COSV99080544; called by muse, mutect2
- PWWP3B | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1339605529, COSV61799393; called by muse, mutect2, varscan2
- SEPTIN4 | c.575G>A p.R192K | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.088); catalogued as COSV58727703; called by muse, mutect2, varscan2
- SH2D4B | c.952G>A p.E318K (on ENST00000646907; = p.E317K on NM_207372.2) | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as rs772363476, COSV100213774; called by muse, mutect2, varscan2
- TSHR | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99991575, COSV99992472; called by muse, mutect2, varscan2
- ZNF530 | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.641); catalogued as COSV60532563; called by muse, mutect2, varscan2
- ADAM33 | c.2335C>T p.P779S | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ADAM33 | c.2334C>T p.D778= | Splice Region (SNP) | VAF 15/53 reads (28%) | called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1373G>T p.C458F | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- COL3A1 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); called by muse, varscan2
- CR1 | c.2534G>A p.S845N | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- EGFLAM | c.1130G>A p.G377D | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ENAM | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 50/183 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPB41L3 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- FAM166A | c.554C>A p.P185H | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- FCHO1 | c.50A>G p.E17G | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- FCRLA | c.302-1G>A p.X101_splice (on ENST00000367959; = p.X78_splice on NM_032738.4) | Splice Site (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2, varscan2
- GABRG2 | c.458G>A p.R153K | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2
- HSD17B3 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 13/181 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.869); called by muse, mutect2
- NAB1 | c.167T>G p.V56G | Missense Mutation (SNP) | VAF 5/106 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NCKAP1 | c.1660C>T p.Q554* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2, varscan2
- PPL | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PRKD1 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 35/247 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- SLC9A3 | c.1682C>T p.S561F | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRIOBP | c.2189C>T p.P730L | Missense Mutation (SNP) | VAF 27/428 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.048); called by muse, mutect2
- TSHZ2 | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2
- TSPYL5 | c.1122G>A p.W374* | Nonsense Mutation (SNP) | VAF 46/159 reads (29%) | called by muse, mutect2, varscan2
- UMODL1 | c.3551_3557dup p.N1186Kfs*6 (on ENST00000408910 / NM_001004416.2; = p.N1314Kfs*6 on NM_173568.3) | Frame Shift Ins (INS) | VAF 41/117 reads (35%) | called by mutect2, varscan2
- ZNF483 | c.1068A>T p.E356D | Missense Mutation (SNP) | VAF 25/314 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.683); called by muse, mutect2
- APOB | c.5526C>T p.I1842= | Silent (SNP) | VAF 11/170 reads (6%) | called by muse, mutect2
- CRYBG3 | c.3411C>T p.S1137= | Silent (SNP) | VAF 7/144 reads (5%) | called by muse, mutect2
- HSD17B3 | c.417C>T p.L139= | Silent (SNP) | VAF 13/185 reads (7%) | catalogued as COSV64557413; called by muse, mutect2
- IL1RAPL1 | c.537C>T p.I179= | Silent (SNP) | VAF 31/158 reads (20%) | catalogued as COSV56237352, COSV56238345; called by muse, mutect2, varscan2
- KCNJ3 | c.39G>A p.Q13= | Silent (SNP) | VAF 31/94 reads (33%) | catalogued as COSV99715544, COSV99715651; called by muse, mutect2, varscan2
- LPA | c.5433G>A p.V1811= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as rs1177257179; called by muse, mutect2, varscan2
- MUC22 | c.1884C>T p.A628= | Silent (SNP) | VAF 66/514 reads (13%) | catalogued as rs527857280; called by muse, mutect2, varscan2
- NRK | c.4383C>T p.I1461= | Silent (SNP) | VAF 13/133 reads (10%) | catalogued as rs267606302; called by muse, mutect2
- OR4Q3 | c.480G>A p.G160= | Silent (SNP) | VAF 13/136 reads (10%) | called by muse, mutect2
- OR51C1P | c.130C>T p.L44= | Silent (SNP) | VAF 10/184 reads (5%) | called by muse, mutect2
- SCN4A | c.2418C>T p.S806= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as rs201306103; called by muse, mutect2, varscan2
- SERPINB2 | c.543C>T p.I181= | Silent (SNP) | VAF 20/126 reads (16%) | catalogued as COSV55091430; called by muse, mutect2, varscan2
- CCDC9B | c.364-229C>T | Intron (SNP) | VAF 3/42 reads (7%) | catalogued as rs1267958609; called by muse, mutect2
- DMKN | c.1383+23C>T | Intron (SNP) | VAF 38/162 reads (23%) | called by muse, mutect2, varscan2
- HOATZ | c.452+177G>A | Intron (SNP) | VAF 6/68 reads (9%) | catalogued as rs1162460150, COSV60441745; called by muse, mutect2
- LRMDA | c.-16C>T | 5'UTR (SNP) | VAF 8/130 reads (6%) | called by muse, mutect2
- NPAP1L | n.113C>T | RNA (SNP) | VAF 28/77 reads (36%) | catalogued as rs1372016029, COSV73747289; called by muse, mutect2, varscan2
- PCDHGA3 | c.2425-67368C>T | Intron (SNP) | VAF 10/308 reads (3%) | called by muse, mutect2
- PHF19 | c.465+18C>T | Intron (SNP) | VAF 8/56 reads (14%) | catalogued as rs768353498; called by muse, mutect2, varscan2
- PITPNM2 | c.2404+641C>T | Intron (SNP) | VAF 6/66 reads (9%) | catalogued as rs763772793; called by muse, mutect2
- TMEM208 | c.-88G>A | 5'UTR (SNP) | VAF 27/182 reads (15%) | catalogued as COSV50774642, COSV99264426; called by muse, mutect2, varscan2
- USP46 | c.36+834G>A | Intron (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2, varscan2
